Somatic mutation profile of tumor specimen TCGA-AX-A2HC-01A (aliquot TCGA-AX-A2HC-01A-11D-A17D-09) from TCGA case TCGA-AX-A2HC, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 53.3 years (19,485 days).
Specimen TCGA-AX-A2HC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1e98e1e-b6a1-4e73-b18e-edf00aa55f1f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A2HC-11A (Solid Tissue Normal), aliquot TCGA-AX-A2HC-11A-11D-A17D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb5852aa-1f4e-439e-b815-981d2dd68384

The open-access MAF lists 14,982 somatic variants for this specimen: 11,658 protein-altering or splice-affecting, 2,975 silent, 349 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10,064, Silent 2,975, Nonsense Mutation 1,153, Splice Site 229, Intron 152, Splice Region 89, RNA 87, Frame Shift Del 63, 3'UTR 56, Frame Shift Ins 47, 5'Flank 20, 5'UTR 17.

Variants (750 of 14,982; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB11 | c.2944G>A p.G982R | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs72549399, CM980249, COSV55599295; ClinVar: pathogenic; called by muse, varscan2
- APC | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 10/17 reads (59%) | hotspot (GDC flag); catalogued as rs121913333, CM942020, COSV57320538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 11/27 reads (41%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 21/49 reads (43%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP7A | c.1831G>T p.E611* | Nonsense Mutation (SNP) | VAF 44/105 reads (42%) | catalogued as rs797045337, COSV100430703; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATRX | c.4862C>T p.T1621M | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs122445106, CM021249, COSV100971718; ClinVar: pathogenic; called by muse, varscan2
- BCL10 | c.136dup p.I46Nfs*4 | Frame Shift Ins (INS) | VAF 12/37 reads (32%) | catalogued as rs387906351; ClinVar: pathogenic; called by mutect2, varscan2
- BRCA1 | c.1714G>T p.E572* | Nonsense Mutation (SNP) | VAF 31/59 reads (53%) | catalogued as rs730881473, CM128922, COSV58783876, COSV58789484; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BUB1B | c.2441G>A p.R814H | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28989182, CM042944, COSV55013078, COSV99806496; ClinVar: pathogenic / affects / uncertain significance; called by muse, mutect2, varscan2
- CBLIF | c.137C>T p.S46L | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs121434322, CM051061; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- CPLANE1 | c.9058C>T p.R3020* | Nonsense Mutation (SNP) | VAF 24/52 reads (46%) | catalogued as rs374144275; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DMD | c.7657C>T p.R2553* | Nonsense Mutation (SNP) | VAF 45/100 reads (45%) | catalogued as rs398124050, CM040026, COSV58905803; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNMT3A | c.2312G>A p.R771Q | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as rs757823678, COSV53037113, COSV53081931; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FGFR1 | c.565C>T p.R189C (on ENST00000447712 / NM_023110.3; = p.R187C on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/237 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs863223331, COSV58332314; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GFAP | c.716G>A p.R239H | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as rs59565950, CM010050, CM023922, CM067416, COSV53652317; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GJB1 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs116840821, CM930323, CM940836; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- GLDC | c.2458-1G>T p.X820_splice | Splice Site (SNP) | VAF 20/42 reads (48%) | catalogued as rs1554643370; ClinVar: likely pathogenic; called by muse, varscan2
- GLRA1 | c.1270G>A p.D424N (on ENST00000455880 / NM_001146040.2; = p.D416N on NM_000171.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/107 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1181626947, COSV51026778; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GNPTG | c.751G>T p.E251* | Nonsense Mutation (SNP) | VAF 12/20 reads (60%) | catalogued as rs1555452081, COSV50189884; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HDAC4 | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064797002, COSV61866558; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- IDS | c.425C>A p.S142Y | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs193302908, CM144665, CM149685, COSV100558236, COSV61712343; ClinVar: pathogenic; called by muse, mutect2
- IRF6 | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1553247774, CM022395, COSV100883930, COSV65420491; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNQ2 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057516085, CM136080, COSV100610433; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.303del p.S102Afs*28 | Frame Shift Del (DEL) | VAF 17/48 reads (35%) | catalogued as rs797045661, CD160605; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRT17 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 35/218 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs28928897, CM012143, CM970840, COSV60860507; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LAMA2 | c.4048C>T p.R1350* | Nonsense Mutation (SNP) | VAF 15/32 reads (47%) | catalogued as rs756854513, CM102055, COSV70343609; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MCCC1 | c.676G>T p.E226* | Nonsense Mutation (SNP) | VAF 15/33 reads (45%) | catalogued as rs1553862845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.2927G>A p.R976H | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs63751113, CM021636, COSV52275309, COSV52291664; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- MYH3 | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs121913623, CM085569; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.1570G>T p.E524* | Nonsense Mutation (SNP) | VAF 20/38 reads (53%) | catalogued as rs1135402815, CM001254, COSV62215915, COSV62225469; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.7348C>T p.R2450* (on ENST00000358273 / NM_001042492.3; = p.R2429* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 24/59 reads (41%) | hotspot (GDC flag); catalogued as rs786202457, CD000998, CM000818, COSV62193225; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 34/64 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960096, COSV67960161, COSV67961129; called by muse, varscan2
- PHF21A | c.1738C>T p.R580* (on ENST00000418153 / NM_001101802.3; = p.R534* on NM_016621.5 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 34/84 reads (40%) | catalogued as rs1565138763, COSV57650092; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 15/32 reads (47%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1381C>T p.R461* (on ENST00000521381 / NM_181523.3; = p.R191* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 13/26 reads (50%) | catalogued as rs1057519838, COSV57125001; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PROC | c.935C>T p.S312L | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs121918160, CM951016, COSV52167582; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PSMD12 | c.367C>T p.R123* | Nonsense Mutation (SNP) | VAF 25/57 reads (44%) | catalogued as rs1114167442, COSV62065273; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.512A>G p.Q171R | Missense Mutation (SNP) | VAF 29/56 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs786204865, CD1513178, CM128491, COSV64288519, COSV64310514; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RB1 | c.2023G>T p.E675* | Nonsense Mutation (SNP) | VAF 38/83 reads (46%) | catalogued as rs137853295, CM920604, COSV57302098, COSV57314492; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.5656C>T p.R1886* (on ENST00000303395 / NM_001202435.3; = p.R1875* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 20/40 reads (50%) | catalogued as rs779614747, CM066997, COSV100321050; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPART | c.696dup p.V233Cfs*8 | Frame Shift Ins (INS) | VAF 12/28 reads (43%) | catalogued as rs770560051; ClinVar: pathogenic; called by mutect2, varscan2
- SRCAP | c.7330C>T p.R2444* | Nonsense Mutation (SNP) | VAF 33/77 reads (43%) | catalogued as rs199469464, CM121172, COSV52667926; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STAT3 | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs113994137, CM077976, COSV52885689; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TECTA | c.2719C>T p.R907* | Nonsense Mutation (SNP) | VAF 13/31 reads (42%) | catalogued as rs764424917, COSV50693039; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TPM1 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397516386, CM1010372; ClinVar: uncertain significance / likely pathogenic; called by muse, varscan2
- TTN | c.99169C>T p.R33057* (on ENST00000591111; = p.R25633* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 24/77 reads (31%) | catalogued as rs727504184, CM144268, COSV100587703; ClinVar: uncertain significance / likely pathogenic; called by muse, varscan2
- USP9X | c.1111C>T p.R371* | Nonsense Mutation (SNP) | VAF 14/31 reads (45%) | catalogued as rs869025592, CM161665, COSV61071116; ClinVar: pathogenic; called by muse, mutect2, varscan2
- VPS13B | c.8119C>T p.R2707* | Nonsense Mutation (SNP) | VAF 55/92 reads (60%) | catalogued as rs386834110, CM076585; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- VWF | c.3922C>T p.R1308C | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs61749387, CM1510477, CM910397; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- WRN | c.3983-1G>T p.X1328_splice | Splice Site (SNP) | VAF 23/44 reads (52%) | catalogued as rs752465293; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A1BG | c.1456G>A p.D486N | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.324); catalogued as COSV54053421; called by muse, mutect2, varscan2
- A2M | c.2834G>A p.R945Q | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs377622666; called by muse, mutect2, varscan2
- A2ML1 | c.216G>T p.K72N | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs747225412; called by muse, mutect2, varscan2
- AARS2 | c.2557C>T p.R853W | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs767391931; called by muse, mutect2
- AASS | c.1679C>A p.P560H | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.977); catalogued as COSV62789579; called by muse, mutect2, varscan2
- ABAT | c.1014C>A p.F338L | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as rs934153114; called by muse, mutect2, varscan2
- ABCA12 | c.5123G>T p.R1708I (on ENST00000272895 / NM_173076.3; = p.R1390I on NM_015657.3) | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.553); catalogued as COSV99792044; called by muse, mutect2, varscan2
- ABCA12 | c.4021G>T p.D1341Y (on ENST00000272895 / NM_173076.3; = p.D1023Y on NM_015657.3) | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs1283205096, COSV99791291; called by muse, mutect2, varscan2
- ABCA13 | c.6358G>A p.E2120K | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.127); catalogued as rs1313453358; called by muse, mutect2, varscan2
- ABCA13 | c.7462G>T p.E2488* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as COSV101447164; called by muse, mutect2, varscan2
- ABCA13 | c.9901C>T p.P3301S | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.777); catalogued as COSV71291305; called by muse, mutect2, varscan2
- ABCA13 | c.12672G>T p.K4224N | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs1253788632; called by muse, mutect2, varscan2
- ABCA13 | c.13638C>T p.F4546= | Splice Region (SNP) | VAF 26/48 reads (54%) | catalogued as rs373145026, COSV68949876; called by muse, mutect2, varscan2
- ABCA13 | c.14528G>A p.R4843H | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs752658494, COSV68947083; called by muse, mutect2, varscan2
- ABCA4 | c.4103G>A p.R1368H | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs761163530, COSV64675771; called by muse, mutect2, varscan2
- ABCA4 | c.2126C>T p.S709L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs374152623; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA6 | c.1894G>T p.D632Y | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV52639826; called by muse, mutect2, varscan2
- ABCA6 | c.1603G>T p.E535* | Nonsense Mutation (SNP) | VAF 17/53 reads (32%) | catalogued as COSV99446125; called by muse, mutect2, varscan2
- ABCA6 | c.54G>T p.K18N | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs755397102, COSV52641172, COSV52645536; called by muse, mutect2, varscan2
- ABCA7 | c.1745G>A p.R582H | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as rs1297568524; called by muse, mutect2, varscan2
- ABCA7 | c.5045G>A p.R1682Q | Missense Mutation (SNP) | VAF 35/57 reads (61%) | SIFT tolerated (0.4); PolyPhen benign (0.19); catalogued as rs747692429; called by muse, mutect2, varscan2
- ABCA9 | c.3592G>T p.E1198* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as COSV100382944; called by muse, mutect2, varscan2
- ABCB1 | c.469C>T p.R157* | Nonsense Mutation (SNP) | VAF 25/63 reads (40%) | catalogued as rs1363838319, COSV55949125, COSV55958612; called by muse, mutect2, varscan2
- ABCB10 | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as rs138468815; called by muse, mutect2, varscan2
- ABCB10 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs555548953; called by muse, mutect2, varscan2
- ABCB11 | c.2872C>T p.R958W | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.72); catalogued as rs766744091, COSV55585662; ClinVar: uncertain significance; called by muse, varscan2
- ABCB4 | c.3716G>A p.R1239H (on ENST00000265723 / NM_018849.3; = p.R1232H on NM_000443.4) | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as rs1160711086; called by muse, mutect2, varscan2
- ABCB4 | c.1679C>T p.T560M | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs185760690; called by muse, mutect2, varscan2
- ABCB4 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.941); catalogued as rs147998447; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCB5 | c.2524C>A p.L842M (on ENST00000404938 / NM_001163941.2; = p.L397M on NM_178559.6) | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV51708911; called by muse, mutect2, varscan2
- ABCB7 | c.1295G>T p.R432I (on ENST00000373394 / NM_001271696.3; = p.R433I on NM_004299.6) | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53720168; called by muse, mutect2, varscan2
- ABCB9 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.608); catalogued as rs778838893; called by muse, mutect2, varscan2
- ABCB9 | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1287075211, COSV54894413; called by muse, mutect2, varscan2
- ABCC1 | c.3343G>A p.A1115T | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as rs371062976; called by muse, mutect2, varscan2
- ABCC11 | c.3777+1G>A p.X1259_splice | Splice Site (SNP) | VAF 5/11 reads (45%) | catalogued as rs140475834; called by muse, mutect2, varscan2
- ABCC4 | c.2993G>A p.R998Q | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as rs767394657; called by muse, mutect2, varscan2
- ABCC5 | c.3022G>A p.A1008T | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as rs760372707; called by muse, mutect2, varscan2
- ABCC5 | c.506G>T p.R169M | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV55587533; called by muse, mutect2, varscan2
- ABCC8 | c.2104C>T p.R702C | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.462); catalogued as rs199732808, COSV100217541; called by muse, varscan2
- ABCC8 | c.1559C>T p.T520M | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.259); catalogued as rs774238698; called by muse, mutect2, varscan2
- ABCC9 | c.2474C>T p.A825V | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs964127282, COSV53973119; called by muse, mutect2, varscan2
- ABCD1 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.069); catalogued as CD961754, COSV99497822; called by muse, mutect2, varscan2
- ABCD1 | c.961C>A p.L321I | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV99497716; called by muse, mutect2, varscan2
- ABCF2 | c.1364G>A p.R455Q | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.833); catalogued as rs1175580450, COSV55184928; called by muse, mutect2, varscan2
- ABCG1 | c.1099C>A p.L367I | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100494442, COSV59202439; called by muse, mutect2, varscan2
- ABCG5 | c.1723C>A p.L575I | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV99571179; called by muse, mutect2, varscan2
- ABCG8 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs763000556; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABHD17A | c.410G>A p.R137H (on ENST00000292577 / NM_001130111.2; = p.R188H on NM_031213.4) | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.619); catalogued as rs765695569, COSV51751523; called by muse, mutect2, varscan2
- ABHD18 | c.1139G>A p.R380Q (on ENST00000398965 / NM_001039717.2; = p.R287Q on NM_025097.2 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); catalogued as rs367696956; called by muse, mutect2, varscan2
- ABL1 | c.2143C>T p.R715C | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs587778014; ClinVar: not provided; called by muse, mutect2, varscan2
- ABTB2 | c.952G>A p.D318N | Missense Mutation (SNP) | VAF 72/139 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs903641747, COSV100131510; called by muse, mutect2, varscan2
- AC005833.1 | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.69); PolyPhen benign (0.125); catalogued as rs766726075, COSV52901257; called by muse, mutect2, varscan2
- AC011455.2 | c.631C>A p.R211S | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.059); catalogued as COSV55500335; called by muse, mutect2, varscan2
- AC013489.1 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.374); catalogued as COSV51552565; called by muse, mutect2, varscan2
- AC020907.6 | c.86C>A p.P29H | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100032574; called by muse, mutect2, varscan2
- AC092143.1 | c.2242G>A p.E748K | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1482084615, COSV59247899; called by muse, mutect2, varscan2
- AC097636.1 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs559038253, COSV71309693; called by muse, mutect2, varscan2
- AC098582.1 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs141601603; called by muse, mutect2, varscan2
- AC109583.1 | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs752846963; called by muse, mutect2, varscan2
- AC245748.1 | c.16-1G>T p.X6_splice | Splice Site (SNP) | VAF 49/104 reads (47%) | catalogued as COSV100495441; called by muse, mutect2, varscan2
- ACAA2 | c.752C>T p.S251L | Missense Mutation (SNP) | VAF 73/110 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748770671; called by muse, mutect2, varscan2
- ACACB | c.7090G>A p.V2364M | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as rs552167251, COSV100623491; called by muse, mutect2, varscan2
- ACAD10 | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766583324, COSV58155640; called by muse, mutect2, varscan2
- ACAD11 | c.605C>T p.S202L | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.693); catalogued as rs369659108, COSV99392936; called by muse, mutect2, varscan2
- ACADSB | c.1100C>T p.A367V | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs745900584, COSV62551468; called by muse, mutect2, varscan2
- ACAN | c.2036C>T p.A679V | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs367992413; called by muse, mutect2, varscan2
- ACAP1 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.425); catalogued as rs769001161, COSV50136660; called by muse, mutect2, varscan2
- ACBD5 | c.1204G>A p.E402K (on ENST00000375888 / NM_001352568.1; = p.E393K on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 71/128 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.167); catalogued as rs777230785, COSV65519169; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACD | c.1405C>T p.R469W (on ENST00000620338; = p.R380W on NM_022914.3) | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs747913250, COSV54667057; called by muse, mutect2, varscan2
- ACKR1 | c.78G>T p.W26C | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as COSV63674583; called by muse, mutect2, varscan2
- ACKR2 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.326); catalogued as COSV99825503; called by muse, mutect2, varscan2
- ACO2 | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1217141951; called by muse, mutect2, varscan2
- ACOT12 | c.1008G>T p.E336D | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.049); catalogued as COSV56898214; called by muse, mutect2, varscan2
- ACOT12 | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 50/100 reads (50%) | catalogued as rs780095623, COSV56892749; called by muse, mutect2, varscan2
- ACOX1 | c.1678C>A p.L560M | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.715); catalogued as rs1419146482; called by muse, mutect2, varscan2
- ACOX3 | c.1753C>T p.R585W | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs746138772; called by muse, mutect2, varscan2
- ACP7 | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1006409955, COSV100488543; called by muse, mutect2, varscan2
- ACSL5 | c.1839+1G>T p.X613_splice (on ENST00000354273; = p.X669_splice on NM_016234.3) | Splice Site (SNP) | VAF 12/28 reads (43%) | catalogued as COSV61131617; called by muse, mutect2
- ACSL6 | c.877G>A p.V293M (on ENST00000379240; = p.V318M on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.18); catalogued as rs375566990; called by muse, mutect2, varscan2
- ACSM2A | c.455C>A p.S152Y (on ENST00000219054; = p.S73Y on NM_001308169.2) | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99525373; called by muse, mutect2, varscan2
- ACTL6A | c.269A>T p.N90I | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV66998589; called by muse, mutect2, varscan2
- ACTL7B | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs773552541, COSV65927773; called by muse, mutect2, varscan2
- ACTL9 | c.1012G>A p.V338M | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1468304638; called by muse, mutect2, varscan2
- ACTN2 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs746677039, COSV100856890; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTN4 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs752949932; called by mutect2, varscan2
- ACTR1A | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1164216858; called by muse, mutect2, varscan2
- ADA | c.216C>T p.I72= | Splice Region (SNP) | VAF 10/26 reads (38%) | catalogued as rs769218320, COSV100866597; called by muse, mutect2, varscan2
- ADAM15 | c.747C>A p.F249L | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55125821, COSV55126633; called by muse, mutect2, varscan2
- ADAM20 | c.709G>A p.V237I | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.59); PolyPhen benign (0.009); catalogued as rs531350369, COSV56454006; called by muse, mutect2, varscan2
- ADAM22 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as rs535039786, COSV55969346; called by muse, mutect2, varscan2
- ADAM29 | c.1886T>A p.F629Y | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.854); catalogued as COSV100822020; called by muse, mutect2, varscan2
- ADAM29 | c.2193G>T p.Q731H | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV63661026, COSV63663870; called by muse, mutect2, varscan2
- ADAM32 | c.1130A>C p.K377T | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.065); catalogued as rs747125299; called by muse, mutect2, varscan2
- ADAM8 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.014); catalogued as rs200268422; called by muse, varscan2
- ADAMTS1 | c.2543C>A p.S848Y | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.541); catalogued as COSV53171619, COSV99536034; called by muse, varscan2
- ADAMTS1 | c.2498G>A p.R833Q | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.096); catalogued as rs552206055, COSV53174406; called by muse, varscan2
- ADAMTS1 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.049); catalogued as rs745862423, COSV99536291; called by muse, mutect2, varscan2
- ADAMTS12 | c.4046C>T p.A1349V | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.207); catalogued as rs764129116, COSV61263595; called by muse, mutect2, varscan2
- ADAMTS12 | c.2794C>T p.P932S | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs764250440; called by muse, mutect2, varscan2
- ADAMTS12 | c.2449C>A p.L817I | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT tolerated (0.39); PolyPhen benign (0.096); catalogued as COSV100710462; called by muse, mutect2
- ADAMTS12 | c.1121G>A p.R374H | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs1287419281, COSV61257410; called by muse, mutect2, varscan2
- ADAMTS14 | c.3083C>A p.S1028Y | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.88); PolyPhen benign (0.054); catalogued as COSV64600016; called by muse, mutect2, varscan2
- ADAMTS15 | c.1666G>A p.E556K | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.403); catalogued as rs752805088, COSV54506224; called by muse, mutect2, varscan2
- ADAMTS15 | c.2128G>A p.D710N | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1440774847; called by muse, mutect2, varscan2
- ADAMTS17 | c.2477C>T p.S826L | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.129); catalogued as rs532333138, COSV51485946; called by muse, mutect2, varscan2
- ADAMTS7 | c.2057G>A p.R686H | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.725); catalogued as rs760894429; called by muse, mutect2, varscan2
- ADAMTS7 | c.1741C>T p.R581C | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750909906; called by muse, mutect2
- ADAMTSL2 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1242674081, COSV63204290; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2663G>A p.R888H | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.218); catalogued as rs978993413; called by muse, mutect2, varscan2
- ADAMTSL3 | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1176590739; called by muse, mutect2, varscan2
- ADAMTSL3 | c.457C>T p.R153* | Nonsense Mutation (SNP) | VAF 42/82 reads (51%) | catalogued as rs754085044, COSV54440177; called by muse, mutect2, varscan2
- ADAMTSL3 | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 45/85 reads (53%) | catalogued as rs771154300, COSV99721988; called by muse, mutect2, varscan2
- ADAR | c.1742C>A p.S581* | Nonsense Mutation (SNP) | VAF 21/54 reads (39%) | catalogued as CM087042; called by muse, mutect2, varscan2
- ADARB1 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.277); catalogued as COSV100653637; called by muse, mutect2, varscan2
- ADAT3 | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.185); catalogued as rs773656522; called by muse, mutect2, varscan2
- ADCY1 | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 49/92 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.149); catalogued as rs903105349, COSV52039695, COSV52040831; called by muse, mutect2, varscan2
- ADCY1 | c.1761C>A p.F587L | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV99812212; called by muse, mutect2, varscan2
- ADCY1 | c.2760G>T p.K920N | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52032629; called by muse, mutect2, varscan2
- ADCY10 | c.3278C>A p.S1093Y | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV63244946; called by muse, mutect2, varscan2
- ADCY10 | c.1421C>T p.A474V | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.646); catalogued as rs764010084, COSV63242283; called by muse, mutect2, varscan2
- ADCY5 | c.3337G>A p.E1113K | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.34); catalogued as rs749774208, COSV59197922; called by muse, mutect2, varscan2
- ADCY8 | c.3025C>T p.R1009C | Missense Mutation (SNP) | VAF 55/88 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1475267602, COSV53905124; called by muse, mutect2, varscan2
- ADCY9 | c.1019G>T p.R340I | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs780726526, COSV99569707; called by muse, mutect2, varscan2
- ADCY9 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.144); catalogued as COSV53574790; called by muse, mutect2, varscan2
- ADD3 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 56/101 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs914623953, COSV53320405; called by muse, mutect2, varscan2
- ADGRA1 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT tolerated (0.63); PolyPhen benign (0.019); catalogued as rs202033807, COSV101192750; called by muse, mutect2, varscan2
- ADGRA2 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as rs755065757; called by muse, mutect2, varscan2
- ADGRA2 | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs1420050120; called by muse, mutect2, varscan2
- ADGRB2 | c.4723G>T p.E1575* (on ENST00000373658 / NM_001364857.2; = p.E1574* on NM_001294335.2) | Nonsense Mutation (SNP) | VAF 40/78 reads (51%) | catalogued as COSV99926542; called by muse, mutect2, varscan2
- ADGRD1 | c.1531G>A p.A511T | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs746391447, COSV55446046; called by muse, mutect2, varscan2
- ADGRD1 | c.1801C>T p.R601C | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs552333041; called by muse, mutect2, varscan2
- ADGRE5 | c.2205G>A p.A735= (on ENST00000242786 / NM_078481.4; = p.A642= on NM_001784.5) | Splice Region (SNP) | VAF 21/47 reads (45%) | catalogued as rs772992066; called by muse, mutect2, varscan2
- ADGRF2 | c.965G>T p.R322I (on ENST00000296862 / NM_001368115.2; = p.R254I on NM_153839.7) | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs898475867; called by muse, mutect2, varscan2
- ADGRF3 | c.365C>T p.A122V (on ENST00000311519 / NM_001145168.1; = p.A63V on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs180836893, COSV100275490; called by muse, mutect2, varscan2
- ADGRF4 | c.822G>T p.Q274H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.169); catalogued as COSV51954062; called by muse, mutect2
- ADGRG2 | c.2888G>T p.R963M (on ENST00000379869 / NM_001079858.3; = p.R960M on NM_005756.4) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV100492604; called by muse, mutect2
- ADGRG2 | c.2550C>A p.F850L (on ENST00000379869 / NM_001079858.3; = p.F847L on NM_005756.4) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.248); catalogued as COSV61338544; called by muse, mutect2, varscan2
- ADGRL3 | c.1039G>T p.E347* (on ENST00000506720 / NM_001322402.2; = p.E279* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 10/19 reads (53%) | catalogued as COSV101546943; called by muse, mutect2, varscan2
- ADGRL3 | c.2525C>A p.S842Y (on ENST00000506720 / NM_001322402.2; = p.S774Y on NM_015236.6) | Missense Mutation (SNP) | VAF 80/138 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV72231375, COSV72232019; called by muse, mutect2, varscan2
- ADGRL3 | c.3722G>A p.R1241Q (on ENST00000506720 / NM_001322402.2; = p.R1173Q on NM_015236.6) | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs143689172; called by muse, mutect2, varscan2
- ADGRV1 | c.3161C>A p.P1054H | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV101315513; called by muse, mutect2, varscan2
- ADGRV1 | c.15049T>G p.S5017A | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV67983070; called by muse, mutect2, varscan2
- ADH1A | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs150829005; called by muse, mutect2, varscan2
- ADIPOR2 | c.1117C>T p.R373C | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); catalogued as rs1321520886, COSV100840004; called by muse, mutect2, varscan2
- ADNP | c.1079C>A p.P360H | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV62426561; called by muse, mutect2, varscan2
- ADPRHL1 | c.802C>T p.R268* | Nonsense Mutation (SNP) | VAF 36/66 reads (55%) | catalogued as rs1463128417; called by muse, mutect2, varscan2
- ADPRHL1 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.659); catalogued as rs375108772; called by muse, mutect2, varscan2
- ADRA2A | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.438); catalogued as COSV99701764; called by mutect2, varscan2
- ADRA2B | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as rs1391914969; called by muse, mutect2, varscan2
- ADRB2 | c.1189G>A p.D397N | Missense Mutation (SNP) | VAF 47/85 reads (55%) | SIFT tolerated (0.58); PolyPhen benign (0.038); catalogued as rs777431854; called by muse, mutect2, varscan2
- ADRB3 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1422835338; called by muse, mutect2, varscan2
- ADTRP | c.14C>A p.S5Y | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.272); catalogued as COSV99995084; called by muse, mutect2, varscan2
- AFAP1L1 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as rs375742704; called by muse, mutect2, varscan2
- AFF1 | c.2314C>T p.R772W | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs368760847, COSV100320293; called by muse, mutect2, varscan2
- AFF3 | c.2009C>T p.S670L | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57852265; called by muse, mutect2, varscan2
- AFF3 | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs1351688871, COSV57881304; called by muse, mutect2, varscan2
- AGAP3 | c.2405C>T p.T802M (on ENST00000622464; = p.T838M on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs746755216; called by muse, mutect2, varscan2
- AGAP4 | c.1778A>G p.N593S | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1464265385; called by mutect2, varscan2
- AGAP4 | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 68/229 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1343213926; called by muse, mutect2, varscan2
- AGAP6 | c.908T>G p.I303S (on ENST00000374056 / NM_001365867.1; = p.I326S on NM_001077665.2) | Missense Mutation (SNP) | VAF 164/380 reads (43%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.721); catalogued as rs1333257092; called by muse, varscan2
- AGL | c.1784G>A p.R595Q | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs753015481; called by muse, mutect2, varscan2
- AGL | c.2379G>T p.E793D | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV99649404; called by muse, mutect2, varscan2
- AGO2 | c.1484C>T p.A495V | Missense Mutation (SNP) | VAF 29/40 reads (73%) | SIFT tolerated (0.1); PolyPhen benign (0.105); catalogued as COSV55046481, COSV55050813; called by muse, mutect2, varscan2
- AGO4 | c.298C>T p.R100W | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs545951478, COSV64616360; called by muse, mutect2, varscan2
- AGPAT3 | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.51); PolyPhen benign (0.069); catalogued as rs1433457216; called by muse, mutect2, varscan2
- AGPS | c.1111C>A p.L371I | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.742); catalogued as COSV51568977; called by muse, mutect2, varscan2
- AGRN | c.4429C>A p.L1477M | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs757439560; called by muse, mutect2
- AHCTF1 | c.5323C>T p.R1775C (on ENST00000366508; = p.R1749C on NM_015446.5) | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs958589626; called by muse, mutect2, varscan2
- AHCTF1 | c.1349C>T p.S450L (on ENST00000366508; = p.S424L on NM_015446.5) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs528013816, COSV58246078; called by muse, mutect2, varscan2
- AHCYL1 | c.377-1G>T p.X126_splice | Splice Site (SNP) | VAF 17/44 reads (39%) | catalogued as COSV63208342; called by muse, mutect2, varscan2
- AHCYL2 | c.1464G>A p.A488= | Splice Region (SNP) | VAF 12/27 reads (44%) | catalogued as rs771428608, COSV100273796; called by muse, mutect2, varscan2
- AHDC1 | c.3505G>A p.D1169N | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs527461367, COSV55938489; called by muse, mutect2, varscan2
- AHDC1 | c.2551G>A p.D851N | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748106770; called by muse, mutect2, varscan2
- AHNAK | c.9202G>A p.E3068K | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.795); catalogued as rs535365338; called by muse, mutect2, varscan2
- AHNAK2 | c.11926C>T p.P3976S | Missense Mutation (SNP) | VAF 79/170 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60919030; called by muse, mutect2, varscan2
- AHNAK2 | c.3020C>T p.S1007L | Missense Mutation (SNP) | VAF 90/190 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs375305203; called by muse, mutect2, varscan2
- AHRR | c.2072C>T p.S691L | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as rs529368124, COSV57091099; called by muse, mutect2, varscan2
- AIF1L | c.100C>A p.L34M | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.429); catalogued as COSV55989410; called by muse, mutect2, varscan2
- AIFM2 | c.480G>T p.E160D | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV57160075; called by muse, mutect2, varscan2
- AK7 | c.461C>T p.T154M | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs763531234; called by muse, mutect2, varscan2
- AK7 | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.928); catalogued as rs773691138; called by muse, mutect2, varscan2
- AKAP11 | c.2304G>T p.Q768H | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0.05); PolyPhen benign (0.233); catalogued as rs768510563; called by muse, mutect2, varscan2
- AKAP12 | c.3535G>A p.D1179N | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs747371302; called by muse, mutect2, varscan2
- AKAP13 | c.4754G>A p.R1585Q | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs181593659, COSV63465642; called by muse, mutect2, varscan2
- AKAP13 | c.6446G>A p.R2149Q (on ENST00000394518 / NM_007200.5; = p.R2153Q on NM_006738.6) | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63456212; called by muse, varscan2
- AKAP4 | c.1131G>T p.E377D | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV100654103, COSV62074891; called by muse, mutect2, varscan2
- AKAP6 | c.590C>A p.S197Y | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV99802941; called by muse, mutect2, varscan2
- AKAP8L | c.1035G>T p.E345D | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV101275822; called by muse, mutect2, varscan2
- AKIRIN2 | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as rs947958170; called by muse, mutect2, varscan2
- AKNA | c.2753C>T p.A918V | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT tolerated (0.71); PolyPhen benign (0.036); catalogued as rs549404488, COSV56314100; called by muse, mutect2, varscan2
- AKR1B1 | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.731); catalogued as rs770279911, COSV53648323; called by muse, mutect2, varscan2
- AKR1C2 | c.55C>A p.L19M | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV101060417; called by muse, mutect2
- AKR1E2 | c.484G>A p.G162R | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761782479, COSV53629953; called by muse, varscan2
- AL133500.1 | c.1229C>T p.A410V | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated, low confidence (0.26); catalogued as rs1310006723, COSV55744332; called by muse, mutect2, varscan2
- AL162417.1 | c.135C>A p.I45= | Splice Region (SNP) | VAF 27/70 reads (39%) | catalogued as COSV100923169; called by muse, mutect2, varscan2
- AL441992.2 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV56916323; called by muse, mutect2, varscan2
- AL645922.1 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs749689628, COSV100191055; called by muse, mutect2, varscan2
- AL645922.1 | c.460G>A p.V154M | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1263973163; called by muse, mutect2, varscan2
- AL645922.1 | c.1934G>A p.R645H | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs559980890; called by muse, mutect2, varscan2
- AL645922.1 | c.3014G>A p.R1005H | Missense Mutation (SNP) | VAF 46/82 reads (56%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.756); catalogued as rs1396098221; called by muse, varscan2
- ALAD | c.612C>A p.F204L | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0.014); catalogued as COSV52958103, COSV99474532; called by muse, mutect2, varscan2
- ALAS1 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.036); catalogued as rs781372666; called by muse, mutect2, varscan2
- ALB | c.1567C>A p.P523T | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55740248; called by muse, mutect2, varscan2
- ALDH16A1 | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.448); catalogued as rs1015091964; called by muse, mutect2, varscan2
- ALDH16A1 | c.1823C>T p.S608L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs978835076; called by muse, mutect2, varscan2
- ALDH16A1 | c.2050G>A p.A684T | Missense Mutation (SNP) | VAF 75/148 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs112736258; called by muse, mutect2, varscan2
- ALDH18A1 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 14/28 reads (50%) | catalogued as COSV100973319; called by muse, mutect2, varscan2
- ALDH1A1 | c.425G>A p.G142D | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1358756447; called by muse, mutect2, varscan2
- ALDOC | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.894); catalogued as rs140001292; called by muse, mutect2, varscan2
- ALG1 | c.898G>T p.E300* | Nonsense Mutation (SNP) | VAF 14/182 reads (8%) | catalogued as COSV99276006; called by muse, mutect2
- ALK | c.654G>T p.Q218H | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.012); catalogued as COSV66588945; called by muse, mutect2, varscan2
- ALKBH3 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs372711510; called by muse, mutect2, varscan2
- ALKBH8 | c.577G>T p.D193Y | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99509202; called by muse, mutect2, varscan2
- ALOX12B | c.1960G>A p.V654M | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as COSV59870999; called by muse, mutect2, varscan2
- ALOX12B | c.1921G>A p.D641N | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV59875623; called by muse, mutect2, varscan2
- ALOXE3 | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs755241389; called by muse, mutect2, varscan2
- ALOXE3 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as rs765727339, COSV59077407; called by muse, mutect2, varscan2
- ALPK1 | c.1636C>T p.R546* | Nonsense Mutation (SNP) | VAF 22/45 reads (49%) | catalogued as rs1388112183, COSV51581917; called by muse, mutect2, varscan2
- ALPK3 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs751544966; called by muse, mutect2, varscan2
- ALPK3 | c.3032C>T p.S1011L | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs374420068; called by muse, mutect2, varscan2
- ALPL | c.73G>T p.D25Y | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV100876902, COSV66379384; called by muse, mutect2, varscan2
- ALS2 | c.2111G>A p.R704Q | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as rs200088152, COSV51884883; called by muse, mutect2, varscan2
- ALS2 | c.1265T>C p.M422T | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT tolerated (0.14); PolyPhen benign (0.158); catalogued as rs372175711; called by muse, mutect2, varscan2
- ALS2CL | c.2197C>T p.R733* | Nonsense Mutation (SNP) | VAF 3/18 reads (17%) | catalogued as CM116866; called by muse, mutect2
- AMBRA1 | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 7/33 reads (21%) | catalogued as COSV100093928; called by muse, mutect2, varscan2
- AMER1 | c.1073G>A p.R358Q | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs374751715, COSV57656038; called by muse, mutect2, varscan2
- AMIGO3 | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs753401818, COSV57537987; called by muse, mutect2, varscan2
- AMMECR1 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99466195; called by muse, mutect2, varscan2
- AMMECR1L | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV55761756; called by muse, mutect2, varscan2
- AMMECR1L | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1411675264, COSV55760064; called by muse, mutect2, varscan2
- AMPD3 | c.1205G>A p.R402H (on ENST00000396553 / NM_001025389.2; = p.R411H on NM_000480.3) | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751465671; called by muse, mutect2, varscan2
- AMPH | c.1622C>A p.P541H | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57740089; called by muse, mutect2, varscan2
- AMPH | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781682680, COSV57737654; called by muse, mutect2, varscan2
- ANGPT2 | c.700del p.I234* | Frame Shift Del (DEL) | VAF 24/90 reads (27%) | catalogued as rs34047276; called by mutect2, varscan2
- ANGPT4 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs958075097; called by muse, mutect2, varscan2
- ANK2 | c.2662C>T p.R888* | Nonsense Mutation (SNP) | VAF 14/35 reads (40%) | catalogued as rs867072234, COSV52156015; called by muse, mutect2, varscan2
- ANK3 | c.9965C>A p.S3322Y | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV55051953; called by muse, mutect2, varscan2
- ANK3 | c.9688C>T p.R3230C | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs145590509, COSV55052665; called by muse, mutect2, varscan2
- ANK3 | c.7543C>A p.L2515I | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.086); catalogued as rs1266079762, COSV55082059, COSV99781928; called by muse, mutect2, varscan2
- ANKAR | c.240C>A p.F80L | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.47); PolyPhen benign (0.173); catalogued as COSV55619344; called by muse, mutect2, varscan2
- ANKAR | c.2952A>C p.Q984H | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as rs1184313830; called by muse, mutect2, varscan2
- ANKFN1 | c.1262G>T p.R421I | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV59447047; called by muse, mutect2, varscan2
- ANKIB1 | c.2305C>T p.R769W | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.998); catalogued as rs547575488; called by muse, mutect2, varscan2
- ANKMY2 | c.1256C>A p.S419Y | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.133); catalogued as COSV100187281; called by muse, mutect2, varscan2
- ANKRD11 | c.245G>T p.R82L | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV56355101; called by muse, mutect2, varscan2
- ANKRD12 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773508611; called by muse, mutect2, varscan2
- ANKRD12 | c.2282C>A p.S761Y | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.243); catalogued as COSV50819090; called by muse, mutect2, varscan2
- ANKRD2 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 59/129 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.325); catalogued as rs769253923; called by muse, mutect2, varscan2
- ANKRD2 | c.228G>T p.E76D | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100080743; called by muse, mutect2, varscan2
- ANKRD2 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs369179658; called by muse, varscan2
- ANKRD20A1 | c.768G>T p.K256N | Missense Mutation (SNP) | VAF 97/199 reads (49%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs200989194; called by muse, mutect2, varscan2
- ANKRD23 | c.421G>T p.D141Y | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs560056848, COSV100450574, COSV58412631; called by muse, mutect2, varscan2
- ANKRD26 | c.2732C>T p.S911L | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373167535; called by muse, mutect2, varscan2
- ANKRD30A | c.1118C>T p.T373M (on ENST00000611781; = p.T317M on NM_052997.2) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as rs374024060, COSV64604651; called by muse, mutect2, varscan2
- ANKRD30A | c.1774G>T p.D592Y (on ENST00000611781; = p.D536Y on NM_052997.2) | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as COSV100654034, COSV64613505; called by muse, mutect2, varscan2
- ANKRD30A | c.4067T>G p.F1356C (on ENST00000611781; = p.F1300C on NM_052997.2) | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as COSV64622930; called by muse, mutect2
- ANKRD34B | c.1033G>T p.D345Y | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV58613677, COSV58614571; called by muse, mutect2, varscan2
- ANKRD35 | c.1577G>A p.R526H | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as rs781993387, COSV100841686, COSV62911363; called by muse, mutect2, varscan2
- ANKS1B | c.2735C>T p.S912L (on ENST00000547776 / NM_152788.4; = p.S138L on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60357807; called by muse, mutect2, varscan2
- ANKS1B | c.2146C>A p.L716M | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV61350139; called by muse, mutect2, varscan2
- ANKS1B | c.1795G>A p.E599K | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.78); PolyPhen benign (0.04); catalogued as COSV61334452; called by muse, mutect2, varscan2
- ANKS1B | c.821C>A p.S274Y | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100248945, COSV61343842; called by muse, mutect2, varscan2
- ANKS3 | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.207); catalogued as rs187743929; called by muse, mutect2, varscan2
- ANO10 | c.927G>T p.K309N | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52731386; called by muse, mutect2, varscan2
- ANO2 | c.317G>A p.R106H (on ENST00000356134 / NM_001278597.3; = p.R110H on NM_001278596.3) | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.347); catalogued as rs773278082, COSV59027862; called by muse, mutect2, varscan2
- ANO2 | c.185G>A p.R62H (on ENST00000356134 / NM_001278597.3; = p.R66H on NM_001278596.3) | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs368125515; called by muse, mutect2, varscan2
- ANO5 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.401); catalogued as rs370084681; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANO5 | c.1637C>A p.P546H | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV61084618; called by muse, varscan2
- ANO6 | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.951); catalogued as rs898041845; called by muse, mutect2, varscan2
- ANO6 | c.1713C>A p.F571L | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761477437, COSV57657199; called by muse, mutect2, varscan2
- ANO9 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 51/96 reads (53%) | SIFT tolerated (0.56); PolyPhen benign (0.022); catalogued as rs773392501; called by muse, mutect2, varscan2
- ANOS1 | c.1021C>A p.L341I | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.119); catalogued as rs767395099; called by muse, mutect2, varscan2
- ANTXR2 | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.677); catalogued as rs756324499, COSV56313262; called by mutect2, varscan2
- ANXA1 | c.840G>T p.E280D | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.997); catalogued as COSV99973918; called by muse, mutect2, varscan2
- ANXA9 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760717286, COSV64484714; called by muse, mutect2, varscan2
- AOAH | c.1619C>T p.A540V | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs763520293, COSV51747609; called by muse, mutect2, varscan2
- AOC2 | c.535C>A p.L179M | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as COSV53198631; called by muse, mutect2, varscan2
- AOC3 | c.34C>A p.L12M | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV99519966; called by muse, mutect2, varscan2
- AP002512.3 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as COSV54406614; called by muse, mutect2, varscan2
- AP002748.5 | c.1489C>T p.R497C | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs745460551; called by muse, mutect2, varscan2
- AP002748.5 | c.1579G>A p.A527T | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.155); catalogued as rs748627604, COSV59151970; called by muse, mutect2, varscan2
- AP1G1 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55485296; called by muse, mutect2, varscan2
- AP1M1 | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766864704; called by muse, mutect2, varscan2
- AP2A2 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as rs542944302; called by muse, mutect2, varscan2
- AP2A2 | c.1259G>A p.R420Q | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV59960158; called by muse, mutect2, varscan2
- AP3B1 | c.1744G>T p.V582F | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT tolerated (0.46); PolyPhen benign (0.03); catalogued as rs199766336; called by muse, mutect2, varscan2
- AP3B2 | c.2336C>T p.S779F | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); catalogued as COSV99916487; called by muse, mutect2, varscan2
- AP5S1 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as rs780228662; called by muse, mutect2, varscan2
- APBB1 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT tolerated (0.23); PolyPhen benign (0.059); catalogued as rs367708086; called by muse, mutect2, varscan2
- APBB1IP | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.996); catalogued as rs373211324; called by muse, mutect2, varscan2
- APBB2 | c.322C>A p.R108S | Missense Mutation (SNP) | VAF 47/96 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55949023; called by muse, mutect2, varscan2
- APBB3 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145695941; called by muse, mutect2, varscan2
- APH1B | c.620C>A p.S207Y | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV56013865; called by muse, mutect2, varscan2
- API5 | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as COSV66633664; called by muse, mutect2, varscan2
- APLP1 | c.1646G>A p.R549Q (on ENST00000221891 / NM_001024807.3; = p.R548Q on NM_005166.4) | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs368942763; called by muse, mutect2, varscan2
- APOA4 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated (0.22); PolyPhen benign (0.329); catalogued as COSV63360597; called by muse, mutect2, varscan2
- APOBEC1 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as rs968565720; called by muse, mutect2, varscan2
- APOBEC1 | c.40C>A p.L14M | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.606); catalogued as COSV57549254, COSV99981063; called by muse, mutect2, varscan2
- APOBEC3D | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs748680344; called by muse, mutect2, varscan2
- APOH | c.566C>T p.T189M | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.996); catalogued as rs376671771; called by muse, varscan2
- APOH | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV52773090; called by muse, mutect2, varscan2
- APP | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs200103591; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APP | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as rs376138420, COSV61006586; called by muse, mutect2, varscan2
- APPL1 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as rs948176239, COSV99897610; called by muse, mutect2
- APPL1 | c.1376C>A p.S459Y | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.971); catalogued as COSV55700394, COSV99897345; called by muse, mutect2, varscan2
- APRT | c.524C>A p.S175Y | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as CM102690; called by muse, mutect2, varscan2
- AQP7 | c.330G>T p.R110S | Missense Mutation (SNP) | VAF 82/166 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as COSV53025047; called by muse, mutect2, varscan2
- AR | c.1852C>T p.R618W | Missense Mutation (SNP) | VAF 65/109 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1218564193, CX116061, COSV65958933; called by muse, mutect2, varscan2
- ARAP2 | c.1056G>T p.K352N | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.102); catalogued as COSV58288508; called by muse, mutect2, varscan2
- ARF3 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.648); catalogued as COSV56741033, COSV56741227; called by muse, mutect2, varscan2
- ARFGEF1 | c.3814C>T p.R1272* | Nonsense Mutation (SNP) | VAF 44/68 reads (65%) | catalogued as COSV51607584; called by muse, mutect2, varscan2
- ARFGEF1 | c.2656G>T p.E886* | Nonsense Mutation (SNP) | VAF 91/139 reads (65%) | catalogued as COSV99143108; called by muse, mutect2, varscan2
- ARFGEF3 | c.4388C>T p.A1463V | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.148); catalogued as rs571551946; called by muse, mutect2, varscan2
- ARHGAP10 | c.1817G>T p.R606I | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.564); catalogued as COSV60598222, COSV60609234; called by muse, mutect2, varscan2
- ARHGAP21 | c.4549C>A p.L1517I | Missense Mutation (SNP) | VAF 111/244 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.419); catalogued as COSV100256205; called by muse, mutect2, varscan2
- ARHGAP21 | c.1366C>T p.R456C | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770619381; called by muse, mutect2, varscan2
- ARHGAP25 | c.739G>A p.V247M (on ENST00000409202 / NM_001007231.3; = p.V239M on NM_014882.3) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs761893650; called by muse, mutect2, varscan2
- ARHGAP29 | c.2326G>T p.E776* | Nonsense Mutation (SNP) | VAF 47/101 reads (47%) | catalogued as COSV53107575, COSV53116559; called by muse, mutect2, varscan2
- ARHGAP31 | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV51798776; called by muse, mutect2, varscan2
- ARHGAP32 | c.2105G>A p.R702H (on ENST00000310343 / NM_001378025.1; = p.R353H on NM_014715.4) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as rs149060649; called by mutect2, varscan2
- ARHGAP33 | c.691C>T p.R231* | Nonsense Mutation (SNP) | VAF 10/18 reads (56%) | catalogued as rs753643359; called by muse, varscan2
- ARHGAP33 | c.3334C>T p.P1112S | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.274); catalogued as rs1261463074; called by muse, mutect2, varscan2
- ARHGAP35 | c.2348G>A p.R783Q | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV68329135; called by muse, mutect2, varscan2
- ARHGAP36 | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 65/134 reads (49%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.976); catalogued as rs778002878, COSV99357560; called by muse, mutect2, varscan2
- ARHGAP39 | c.1823C>T p.A608V | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1319412093, COSV52770232; called by muse, varscan2
- ARHGAP4 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs1457829264, COSV63135216; called by muse, mutect2, varscan2
- ARHGAP5 | c.986A>T p.E329V | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100565580; called by muse, varscan2
- ARHGEF10L | c.1928-1G>T p.X643_splice | Splice Site (SNP) | VAF 19/38 reads (50%) | catalogued as COSV51436507; called by muse, mutect2, varscan2
- ARHGEF11 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766437692; called by muse, mutect2, varscan2
- ARHGEF17 | c.4399G>A p.D1467N | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.23); PolyPhen benign (0.153); catalogued as rs781426389, COSV55229808; called by muse, mutect2, varscan2
- ARHGEF17 | c.4642G>A p.A1548T | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1213688861, COSV99736870; called by muse, mutect2, varscan2
- ARHGEF17 | c.5767C>T p.R1923* | Nonsense Mutation (SNP) | VAF 33/68 reads (49%) | catalogued as rs747241781, COSV55238664; called by muse, mutect2, varscan2
- ARHGEF38 | c.201G>T p.K67N | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV54442114, COSV54442497; called by muse, mutect2, varscan2
- ARHGEF40 | c.388C>T p.R130W | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1184715356; called by muse, mutect2, varscan2
- ARHGEF6 | c.763G>T p.E255* | Nonsense Mutation (SNP) | VAF 11/20 reads (55%) | catalogued as COSV51689165, COSV99166766; called by muse, mutect2, varscan2
- ARHGEF7 | c.1021G>A p.E341K (on ENST00000375741 / NM_001113511.2; = p.E163K on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as rs753457702; called by muse, mutect2, varscan2
- ARHGEF9 | c.997G>A p.G333S | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.375); catalogued as rs782103101, COSV53636040; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGEF9 | c.614G>A p.C205Y | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99492072; called by muse, mutect2, varscan2
- ARHGEF9 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0.111); catalogued as rs374489713; called by muse, mutect2, varscan2
- ARID1A | c.3539+1G>A p.X1180_splice | Splice Site (SNP) | VAF 15/33 reads (45%) | catalogued as COSV61383415, COSV61385140; called by muse, mutect2, varscan2
- ARID1A | c.4111C>T p.R1371W | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61391104; called by muse, mutect2, varscan2
- ARID1A | c.4631C>T p.S1544L | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs1326693674, COSV99055360; called by muse, mutect2, varscan2
- ARID3C | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1164276941, COSV52409257; called by muse, mutect2, varscan2
- ARID4B | c.3175C>T p.R1059* | Nonsense Mutation (SNP) | VAF 41/82 reads (50%) | catalogued as COSV51599070, COSV51599207; called by muse, varscan2
- ARID4B | c.2665C>A p.L889I | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.952); catalogued as rs755714856, COSV51610010; called by muse, mutect2, varscan2
- ARID5A | c.1334G>A p.R445H | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs139848963, COSV62591023; called by muse, mutect2
- ARL1 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1033216289, COSV55370222; called by muse, mutect2, varscan2
- ARL11 | c.584G>T p.R195I | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.027); catalogued as rs1458149068, COSV99948990; called by muse, mutect2, varscan2
- ARL13B | c.10C>A p.L4M | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.405); catalogued as COSV57399983; called by muse, mutect2, varscan2
- ARL14 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs754095868; called by muse, mutect2, varscan2
- ARL14 | c.507G>T p.R169S | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as COSV100296448; called by muse, mutect2, varscan2
- ARL2 | c.140C>T p.T47M | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV99880459; called by muse, mutect2, varscan2
- ARL6 | c.381C>A p.F127L | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.498); catalogued as COSV60117637, COSV60118364; called by muse, mutect2, varscan2
- ARL6IP6 | c.5C>A p.S2* | Nonsense Mutation (SNP) | VAF 35/67 reads (52%) | catalogued as COSV58443949; called by muse, mutect2, varscan2
- ARMC1 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT tolerated (0.07); PolyPhen benign (0.15); catalogued as rs773610877; called by muse, varscan2
- ARMC1 | c.389A>C p.K130T | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as rs1218961669; called by muse, mutect2, varscan2
- ARMC3 | c.916C>T p.P306S | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs761740326, COSV99957854; called by muse, mutect2, varscan2
- ARMC3 | c.1880G>T p.S627I | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.343); catalogued as COSV53066660; called by muse, mutect2, varscan2
- ARMC3 | c.2392C>T p.R798* | Nonsense Mutation (SNP) | VAF 29/55 reads (53%) | catalogued as rs756308547, COSV53066164; called by muse, mutect2, varscan2
- ARMCX3 | c.916C>A p.L306M | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57869981; called by muse, mutect2, varscan2
- ARNTL | c.827G>A p.R276Q (on ENST00000403290 / NM_001297719.2; = p.R275Q on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.038); catalogued as rs1254604798, COSV62986299; called by muse, mutect2, varscan2
- ARNTL2 | c.1798G>A p.D600N | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs200883018; called by muse, mutect2, varscan2
- ARPP21 | c.147G>T p.Q49H | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.991); catalogued as rs1288627038, COSV99493039; called by muse, mutect2, varscan2
- ARPP21 | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs535388566, COSV51802472; called by muse, varscan2
- ARPP21 | c.1065G>A p.W355* | Nonsense Mutation (SNP) | VAF 16/25 reads (64%) | catalogued as COSV51807764; called by muse, mutect2, varscan2
- ARPP21 | c.1952C>T p.T651M | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as rs139862817; called by muse, mutect2, varscan2
- ARRDC3 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs756630990, COSV99475117; called by muse, mutect2, varscan2
- ARRDC3 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 43/76 reads (57%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1394065046, COSV54366693; called by muse, mutect2, varscan2
- ARSD | c.1009C>A p.L337I | Missense Mutation (SNP) | VAF 37/60 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV54203534; called by muse, mutect2, varscan2
- ARSG | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.636); catalogued as rs781372500, COSV71593895; called by muse, mutect2, varscan2
- ARSH | c.1215G>T p.Q405H | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV66962562; called by muse, mutect2, varscan2
- ARSJ | c.405G>T p.Q135H | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs920461976; called by muse, mutect2, varscan2
- ARVCF | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as rs948347766; called by muse, mutect2, varscan2
- AS3MT | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.509); catalogued as COSV100185869; called by muse, mutect2, varscan2
- ASAP1 | c.2755G>A p.E919K | Missense Mutation (SNP) | VAF 42/64 reads (66%) | SIFT tolerated (0.36); PolyPhen benign (0.053); catalogued as rs768671699, COSV63050217; called by muse, mutect2, varscan2
- ASAP2 | c.1286G>A p.R429K | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.245); catalogued as COSV55634949; called by muse, mutect2
- ASAP2 | c.1793G>A p.R598Q | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.975); catalogued as rs919010572, COSV55634729, COSV55636496; called by muse, mutect2, varscan2
- ASB11 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 43/83 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.376); catalogued as rs199598614, COSV60355931; called by muse, mutect2, varscan2
- ASB11 | c.540G>T p.E180D | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as COSV100728956; called by muse, mutect2, varscan2
- ASB15 | c.1601C>A p.P534H | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99306352; called by muse, mutect2, varscan2
- ASB16 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.144); catalogued as rs1234743136; called by muse, mutect2, varscan2
- ASB7 | c.859C>T p.R287* | Nonsense Mutation (SNP) | VAF 20/43 reads (47%) | catalogued as COSV60417431; called by muse, varscan2
- ASCC3 | c.2362C>T p.R788W | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770792318, COSV61228447; called by muse, mutect2, varscan2
- ASH1L | c.4350G>T p.E1450D | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.07); catalogued as rs908823813; called by muse, mutect2, varscan2
- ASIC1 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs916356955; called by muse, mutect2, varscan2
- ASIC4 | c.1079G>A p.R360H (on ENST00000347842 / NM_182847.3; = p.R379H on NM_018674.6) | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1322492541, COSV61730801; called by muse, mutect2, varscan2
- ASL | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as rs775839623, COSV59187908; called by muse, mutect2, varscan2
- ASL | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 88/148 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1428029508, CM141229, COSV100508825; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASPH | c.823G>T p.E275* | Nonsense Mutation (SNP) | VAF 18/60 reads (30%) | catalogued as COSV62860360; called by muse, mutect2, varscan2
- ASPHD2 | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 44/76 reads (58%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.988); catalogued as rs1184646439; called by muse, mutect2, varscan2
- ASPN | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT tolerated (0.38); PolyPhen benign (0.072); catalogued as rs765686923, COSV65015855; called by muse, mutect2, varscan2
- ASPRV1 | c.638C>A p.S213Y | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV57227719; called by muse, mutect2, varscan2
- ASTN1 | c.3010C>T p.R1004* | Nonsense Mutation (SNP) | VAF 12/19 reads (63%) | catalogued as rs1357604735, COSV62493153; called by muse, mutect2, varscan2
- ASTN1 | c.2266C>T p.R756C | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1177834978, COSV56065131; called by muse, mutect2, varscan2
- ASTN1 | c.1498C>T p.R500W | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs752367629, COSV56060646; called by muse, mutect2, varscan2
- ASTN2 | c.2579G>A p.R860Q (on ENST00000313400 / NM_001365069.1; = p.R809Q on NM_014010.5) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.994); catalogued as rs766074874, COSV57764941; called by muse, mutect2, varscan2
- ASXL1 | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1299423705, COSV60107868, COSV60111358; called by muse, mutect2, varscan2
- ASXL1 | c.1759G>T p.G587C | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764414702; called by muse, mutect2, varscan2
- ASXL1 | c.4099G>A p.V1367I | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs147456014; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASXL2 | c.934C>T p.R312* | Nonsense Mutation (SNP) | VAF 23/39 reads (59%) | catalogued as COSV55456602; called by muse, mutect2, varscan2
- ASXL3 | c.343G>T p.E115* | Nonsense Mutation (SNP) | VAF 5/36 reads (14%) | catalogued as COSV52483155; called by muse, mutect2, varscan2
- ASXL3 | c.1508T>G p.V503G | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs747353588; called by muse, mutect2, varscan2
- ASXL3 | c.3166G>T p.D1056Y | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99322806; called by muse, mutect2, varscan2
- ASZ1 | c.1231G>T p.D411Y | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV52913632, COSV99498153; called by muse, mutect2, varscan2
- ATAD2 | c.354del p.E119Kfs*8 | Frame Shift Del (DEL) | VAF 22/74 reads (30%) | catalogued as rs746676748; called by mutect2, varscan2
- ATAD5 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.172); catalogued as COSV58976335; called by muse, mutect2, varscan2
- ATAD5 | c.4206C>A p.F1402L | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as rs1139210; called by muse, varscan2
- ATG16L1 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs746840032, COSV61465102; called by muse, mutect2, varscan2
- ATG2B | c.5459G>A p.R1820Q | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.992); catalogued as rs760536921, COSV99952041; called by mutect2, varscan2
- ATG2B | c.5376G>T p.K1792N | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99952093; called by muse, mutect2, varscan2
- ATG2B | c.1593G>T p.Q531H | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV63423891; called by muse, mutect2, varscan2
- ATG4C | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 59/95 reads (62%) | SIFT tolerated (0.34); PolyPhen benign (0.075); catalogued as rs750198093; called by muse, mutect2, varscan2
- ATG7 | c.1259G>A p.R420Q | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as rs200554907; called by muse, mutect2, varscan2
- ATIC | c.1474G>A p.D492N | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs771474223; called by muse, mutect2, varscan2
- ATL2 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60050572; called by muse, mutect2, varscan2
- ATM | c.1319C>T p.S440F | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.023); catalogued as rs773895161; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATM | c.7162C>T p.L2388F | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.281); catalogued as COSV53730136; called by muse, mutect2, varscan2
- ATM | c.7925G>T p.R2642I | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as CD120361; called by muse, mutect2, varscan2
- ATM | c.8524C>T p.P2842S | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs876659505; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP10A | c.1210G>T p.D404Y | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs960118811; called by muse, mutect2, varscan2
- ATP10D | c.37C>T p.R13* | Nonsense Mutation (SNP) | VAF 26/56 reads (46%) | catalogued as rs774800431; called by muse, mutect2, varscan2
- ATP10D | c.2600G>T p.S867I | Missense Mutation (SNP) | VAF 40/65 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs147675892; called by muse, mutect2, varscan2
- ATP10D | c.2941G>T p.D981Y | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV56709539; called by muse, mutect2, varscan2
- ATP11B | c.1177G>A p.D393N | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.709); catalogued as COSV60026701; called by muse, mutect2, varscan2
- ATP13A1 | c.1067C>A p.S356Y | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52290899; called by muse, mutect2, varscan2
- ATP13A3 | c.3586C>T p.R1196W (on ENST00000645319 / NM_001367549.1; = p.R1166W on NM_024524.3) | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs927986967; called by muse, mutect2, varscan2
- ATP13A5 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs776380026, COSV60868282; called by muse, mutect2, varscan2
- ATP1A2 | c.2581G>T p.G861C | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV100767712; called by muse, mutect2, varscan2
- ATP1A3 | c.2333C>T p.S778F (on ENST00000545399 / NM_001256214.2; = p.S765F on NM_152296.5) | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57492253; called by muse, mutect2, varscan2
- ATP1A3 | c.2047G>A p.E683K (on ENST00000545399 / NM_001256214.2; = p.E670K on NM_152296.5) | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.048); catalogued as rs782439924, COSV57486709; called by muse, mutect2, varscan2
- ATP1A4 | c.1895C>T p.A632V | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs761126045; called by muse, varscan2
- ATP1A4 | c.1951G>A p.A651T | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.215); catalogued as rs769485753, COSV100927581, COSV63629152; called by muse, varscan2
- ATP1B2 | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT tolerated (0.08); PolyPhen benign (0.155); catalogued as COSV100006921; called by muse, mutect2, varscan2
- ATP2A1 | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV59461589; called by muse, mutect2, varscan2
- ATP2A2 | c.2839C>A p.L947I | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.113); catalogued as COSV100428887; called by muse, mutect2, varscan2
- ATP2B2 | c.1892C>T p.A631V (on ENST00000352432; = p.A597V on NM_001683.5) | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs753859888, COSV59508911; called by muse, mutect2, varscan2
- ATP2B3 | c.1733C>T p.S578L | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54847168; called by muse, mutect2, varscan2
- ATP4A | c.1095G>T p.K365N | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52870777; called by muse, mutect2, varscan2
- ATP6AP1 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV100645172, COSV100645186; called by muse, mutect2, varscan2
- ATP6V0A1 | c.196C>T p.R66* | Nonsense Mutation (SNP) | VAF 22/55 reads (40%) | catalogued as COSV52877573; called by muse, mutect2, varscan2
- ATP6V0A2 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as rs199698721, COSV57749267; called by muse, mutect2, varscan2
- ATP6V0A4 | c.2258-1G>T p.X753_splice | Splice Site (SNP) | VAF 9/15 reads (60%) | catalogued as CS148446, COSV100022692; called by muse, mutect2
- ATP6V0A4 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs894665573, COSV59474270; called by muse, mutect2, varscan2
- ATP6V1C1 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1388747539, COSV67777615; called by muse, mutect2, varscan2
- ATP6V1G2 | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.734); catalogued as rs749507285; called by muse, mutect2, varscan2
- ATP7A | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV58455777; called by muse, mutect2, varscan2
- ATP7B | c.701G>T p.R234I | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as COSV54435370, COSV99666591; called by muse, mutect2, varscan2
- ATP8A1 | c.2713C>T p.P905S | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV52535589; called by muse, mutect2, varscan2
- ATP8B4 | c.1564G>T p.E522* | Nonsense Mutation (SNP) | VAF 34/64 reads (53%) | catalogued as COSV52709677; called by muse, mutect2, varscan2
- ATP9A | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1194861517, COSV58762840, COSV58770385; called by muse, mutect2, varscan2
- ATP9B | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs776708241; called by muse, mutect2, varscan2
- ATP9B | c.2266C>T p.R756C | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs976628308; called by muse, mutect2, varscan2
- ATR | c.7777C>A p.L2593I | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.099); catalogued as COSV53808233; called by muse, mutect2, varscan2
- ATR | c.3898C>T p.R1300C | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779170933, COSV63386190; called by muse, varscan2
- ATR | c.3789G>T p.K1263N | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1472876650; called by muse, mutect2, varscan2
- ATR | c.482G>T p.R161I | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.012); catalogued as COSV63383692; called by muse, mutect2, varscan2
- ATRX | c.5375C>A p.S1792Y | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64883138; called by muse, mutect2, varscan2
- ATRX | c.4365G>T p.E1455D | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV104428837; called by muse, mutect2, varscan2
- ATRX | c.227C>T p.S76L | Missense Mutation (SNP) | VAF 52/98 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs782664370; called by muse, varscan2
- ATXN2 | c.1208G>A p.R403Q (on ENST00000550104; = p.R243Q on NM_002973.4) | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as rs776935081, COSV101112602; called by muse, mutect2, varscan2
- ATXN2L | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs751956607; called by muse, mutect2, varscan2
- ATXN7L3 | c.545C>A p.P182H (on ENST00000389384 / NM_001382309.1; = p.P189H on NM_001382308.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.146); catalogued as COSV60229092; called by muse, mutect2, varscan2
- AUH | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774105176, COSV57866965; called by muse, varscan2
- AUP1 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1558607177; called by muse, mutect2, varscan2
- AUTS2 | c.2136C>A p.F712L | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.595); catalogued as COSV61392040, COSV61420254; called by muse, mutect2, varscan2
- AXIN1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs377639730, COSV51986728, COSV51990434, COSV99249701; called by muse, mutect2, varscan2
- AXL | c.2287C>T p.R763C (on ENST00000301178 / NM_021913.5; = p.R754C on NM_001699.6) | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as rs746364612, COSV56571852; called by muse, mutect2, varscan2
- AZIN2 | c.1030-1G>T p.X344_splice | Splice Site (SNP) | VAF 52/100 reads (52%) | catalogued as COSV53855902, COSV53856686; called by muse, mutect2, varscan2
- B2M | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 74/75 reads (99%) | catalogued as COSV62563116; called by muse, mutect2, varscan2
- B3GALT2 | c.339G>T p.E113D | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.038); catalogued as COSV66463845; called by muse, mutect2, varscan2
- B3GLCT | c.1167C>A p.Y389* | Nonsense Mutation (SNP) | VAF 31/53 reads (58%) | catalogued as COSV58459589; called by muse, mutect2, varscan2
- B3GNT5 | c.157A>G p.N53D | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV100191819; called by muse, mutect2, varscan2
- B3GNTL1 | c.130G>T p.D44Y | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs111333063; called by muse, mutect2, varscan2
- B4GALNT1 | c.1385-1G>T p.X462_splice | Splice Site (SNP) | VAF 6/14 reads (43%) | catalogued as COSV57544805; called by muse, mutect2, varscan2
- B4GALNT1 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV57543266; called by muse, mutect2, varscan2
- B4GALNT3 | c.2668G>A p.D890N | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs753895546; called by muse, mutect2, varscan2
- B4GALNT4 | c.2590G>A p.E864K | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.05); PolyPhen benign (0.258); catalogued as rs975546756; called by muse, mutect2, varscan2
- B4GALT3 | c.247C>T p.L83F | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV60527623, COSV60527892; called by muse, mutect2, varscan2
- B4GALT4 | c.535C>A p.L179I | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT tolerated (0.23); PolyPhen benign (0.046); catalogued as COSV63295638; called by muse, mutect2, varscan2
- BACE2 | c.750C>A p.V250= | Splice Region (SNP) | VAF 38/78 reads (49%) | catalogued as COSV57741441; called by muse, mutect2
- BAD | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99657794; called by muse, mutect2, varscan2
- BAHCC1 | c.1792G>A p.E598K | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs369734156; called by muse, mutect2, varscan2
- BAHD1 | c.2249G>A p.R750H | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.239); catalogued as COSV60378771; called by muse, mutect2, varscan2
- BAIAP2 | c.363G>T p.K121N | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58334057, COSV58341242; called by muse, varscan2
- BAIAP3 | c.3241G>A p.E1081K | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs567104517, COSV50104889; called by muse, mutect2
- BARHL1 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as rs55836017, COSV55037260; called by muse, varscan2
- BAZ2A | c.5663G>A p.R1888H | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.238); catalogued as rs551372747, COSV51635708; called by muse, mutect2, varscan2
- BBOF1 | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 19/39 reads (49%) | catalogued as COSV58220531; called by muse, mutect2, varscan2
- BBS5 | c.446A>G p.N149S | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.133); catalogued as COSV99752208; called by muse, mutect2, varscan2
- BCAM | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.773); catalogued as rs139289024; called by muse, mutect2, varscan2
- BCAN | c.2044G>A p.D682N | Missense Mutation (SNP) | VAF 53/100 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs1349233161, COSV100228654, COSV61256811; called by muse, mutect2, varscan2
- BCAR3 | c.1616G>A p.R539H | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs143508660; called by muse, mutect2, varscan2
- BCAR3 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.365); catalogued as COSV53072446; called by muse, mutect2, varscan2
- BCAT1 | c.304C>T p.R102* | Nonsense Mutation (SNP) | VAF 22/52 reads (42%) | catalogued as rs754324341, COSV53918429; called by muse, mutect2, varscan2
- BCAT2 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs150116784; called by muse, mutect2, varscan2
- BCAT2 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760322244; called by muse, mutect2, varscan2
- BCHE | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as rs749068794, COSV52256399; called by muse, mutect2, varscan2
- BCHE | c.583G>A p.G195S | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52255342; called by muse, mutect2, varscan2
- BCL2 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.491); catalogued as rs766508625, COSV61373555, COSV61383745; called by muse, mutect2, varscan2
- BCLAF1 | c.473G>A p.R158K | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.3); catalogued as COSV62140901; called by muse, mutect2, varscan2
- BCO2 | c.1525G>T p.E509* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as COSV63062580; called by mutect2, varscan2
- BCORL1 | c.1826G>A p.R609Q | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54407536; called by muse, varscan2
- BCORL1 | c.4606C>T p.R1536C | Missense Mutation (SNP) | VAF 48/94 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs868071876, COSV54393391, COSV54407721; called by muse, mutect2, varscan2
- BCR | c.2176C>T p.R726C | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1410579779, COSV100005713; called by muse, mutect2, varscan2
- BDP1 | c.2419C>A p.L807I | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.088); catalogued as rs745904337; called by muse, mutect2, varscan2
- BDP1 | c.7090C>A p.L2364I | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.303); catalogued as rs1365971594; called by muse, mutect2, varscan2
- BEGAIN | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs943461909, COSV100766950; called by muse, mutect2, varscan2
- BEND2 | c.1406C>A p.S469Y | Missense Mutation (SNP) | VAF 62/124 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.552); catalogued as COSV66216251; called by muse, mutect2, varscan2
- BEND4 | c.920C>A p.S307* | Nonsense Mutation (SNP) | VAF 11/24 reads (46%) | catalogued as COSV72469404; called by muse, mutect2, varscan2
- BHMT | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 23/54 reads (43%) | catalogued as COSV57154611; called by muse, mutect2, varscan2
- BICD2 | c.2170G>A p.E724K | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs776152202, COSV63548515; called by muse, mutect2, varscan2
- BICRA | c.2131G>A p.A711T | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs553083032; called by muse, varscan2
- BID | c.301G>A p.D101N (on ENST00000317361 / NM_197966.2; = p.D55N on NM_001196.4) | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); catalogued as rs1333326559; called by muse, mutect2, varscan2
- BIN1 | c.703G>A p.V235I (on ENST00000316724 / NM_001320642.1; = p.V204I on NM_004305.4) | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.444); catalogued as rs772153287; called by muse, mutect2, varscan2
- BIN2 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758843494, COSV99909600; called by muse, mutect2, varscan2
- BIN3 | c.183G>T p.K61N | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV52385993; called by muse, mutect2, varscan2
- BIRC2 | c.545G>A p.S182N | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs777091998, COSV57162509; called by muse, mutect2, varscan2
- BIRC2 | c.1654G>T p.D552Y | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs371742922; called by muse, mutect2, varscan2
- BIRC3 | c.20G>T p.S7I | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); catalogued as COSV54816597; called by muse, mutect2, varscan2
- BIRC6 | c.6070C>T p.R2024C | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143036929; called by muse, mutect2, varscan2
- BIRC6 | c.8551G>A p.V2851I | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.761); catalogued as rs1162352281; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3031G>A p.D1011N | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs144645075, COSV63243825; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4289C>A p.S1430Y | Missense Mutation (SNP) | VAF 30/46 reads (65%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as COSV100863556; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4682G>T p.S1561I | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.074); catalogued as rs1314124196; called by muse, varscan2
- BLCAP | c.233C>T p.S78L | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); catalogued as rs1384184662, COSV50351000; called by muse, mutect2, varscan2
- BLNK | c.1195C>T p.R399* | Nonsense Mutation (SNP) | VAF 26/59 reads (44%) | catalogued as rs1554894837; called by muse, mutect2, varscan2
- BMF | c.11C>A p.S4Y | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.323); catalogued as COSV99590441; called by muse, mutect2, varscan2
- BMP1 | c.2014G>A p.E672K | Missense Mutation (SNP) | VAF 51/75 reads (68%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.87); catalogued as rs145735409; called by muse, mutect2, varscan2
- BMP15 | c.985C>T p.R329C | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as rs782375794, CM100080, COSV99399521; called by muse, mutect2, varscan2
- BMP2K | c.2853G>T p.E951D | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.875); catalogued as COSV99785073; called by muse, mutect2, varscan2
- BMP3 | c.1408G>A p.A470T | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763946969, COSV51081761; called by muse, mutect2, varscan2
- BMP5 | c.878G>T p.G293V | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63704158; called by muse, mutect2, varscan2
- BMP5 | c.669G>T p.K223N | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as COSV63704241; called by muse, mutect2, varscan2
- BMPR1A | c.1456C>T p.R486W | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs767763451, COSV64407060; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMS1 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 140/311 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs764818907, COSV100996700; called by muse, mutect2, varscan2
- BMX | c.854C>A p.S285Y | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.23); catalogued as rs751881194; called by muse, varscan2
- BNC2 | c.2971G>A p.D991N | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as rs753276488, COSV66168550; called by muse, mutect2, varscan2
- BNC2 | c.1282C>T p.R428W | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs756459154, COSV101033320, COSV66149708; called by muse, mutect2, varscan2
- BNIP1 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs370583969; called by muse, mutect2, varscan2
- BNIP1 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.18); catalogued as rs780853583; called by muse, mutect2, varscan2
- BNIP1 | c.599C>T p.T200M | Missense Mutation (SNP) | VAF 63/117 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372089930; called by muse, mutect2, varscan2
- BOC | c.1705C>T p.R569W | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs763721866, COSV56348003; called by muse, varscan2
- BOP1 | c.1706G>A p.R569H | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.794); catalogued as rs1045629687; called by muse, mutect2
- BORCS7 | c.219G>T p.M73I | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.465); catalogued as COSV100185757; called by muse, mutect2, varscan2
- BPGM | c.489G>T p.E163D | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV61323814; called by muse, mutect2, varscan2
- BPIFB1 | c.25C>A p.L9I | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as rs936547140; called by muse, mutect2, varscan2
- BPIFB3 | c.744+1G>A p.X248_splice | Splice Site (SNP) | VAF 28/59 reads (47%) | catalogued as rs145289801, COSV64956920; called by muse, mutect2, varscan2
- BPIFB6 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as rs755029595, COSV99051283; called by muse, mutect2, varscan2
- BPTF | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1296511646; called by muse, mutect2, varscan2
- BPTF | c.6925C>T p.P2309S | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs1555673272; called by muse, mutect2, varscan2
- BRCA2 | c.1075G>T p.E359* | Nonsense Mutation (SNP) | VAF 11/31 reads (35%) | catalogued as COSV66448578, COSV66450599; called by muse, mutect2, varscan2
- BRCA2 | c.2396A>G p.K799R | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.104); catalogued as rs1555282656; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.6290C>T p.T2097M | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as rs80358866; ClinVar: benign / conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2, varscan2
- BRCA2 | c.9020G>T p.R3007I | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66456663; called by muse, mutect2, varscan2
- BRD1 | c.2689G>A p.E897K (on ENST00000216267 / NM_001349940.1; = p.E1028K on NM_001304808.3) | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.179); catalogued as rs1429372853; called by muse, mutect2, varscan2
- BRD1 | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 12/17 reads (71%) | catalogued as rs777684239; called by muse, varscan2
- BRD4 | c.4081C>A p.L1361I | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as COSV54590178, COSV99650932; called by muse, mutect2, varscan2
- BRD9 | c.1633C>T p.R545W | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs761934433, COSV60245090; called by muse, mutect2, varscan2
- BRICD5 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.096); catalogued as rs774953680; called by muse, varscan2
- BRINP3 | c.1118T>C p.V373A | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.76); PolyPhen benign (0.092); catalogued as rs747787642, COSV66513032, COSV66525484; called by muse, mutect2, varscan2
- BRINP3 | c.405C>A p.F135L | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV66518014, COSV66518629; called by muse, mutect2, varscan2
- BRIP1 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs759031349; ClinVar: uncertain significance / likely benign; called by muse, varscan2
- BRSK2 | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs746658894, COSV57545295; called by muse, mutect2, varscan2
- BRWD1 | c.2272C>T p.R758* | Nonsense Mutation (SNP) | VAF 13/21 reads (62%) | catalogued as rs764984038, COSV60900965; called by muse, mutect2, varscan2
- BRWD3 | c.2249G>A p.R750Q | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs1389357356; called by muse, mutect2, varscan2
- BST1 | c.26C>T p.S9L | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV53946547; called by muse, mutect2, varscan2
- BTBD2 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV99724717; called by muse, mutect2, varscan2
- BTBD9 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as rs373397078, COSV104403735; called by muse, mutect2, varscan2
- BTNL9 | c.937C>T p.R313W | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs146697971; called by muse, mutect2, varscan2
- BTNL9 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.765); catalogued as COSV59798559; called by muse, mutect2
- BUD13 | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs758268223, COSV52767165; called by muse, mutect2, varscan2
- BUD13 | c.217G>T p.D73Y | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as rs758106000, COSV52768619; called by muse, mutect2, varscan2
- BZW2 | c.409C>T p.L137F | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs1377038665; called by muse, mutect2, varscan2
- C10orf120 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1431253930, COSV61491778, COSV61492642; called by muse, mutect2, varscan2
- C10orf67 | c.204G>A p.T68= (on ENST00000323327; = p.T69= on NM_153714.3) | Splice Region (SNP) | VAF 16/46 reads (35%) | catalogued as rs1299815678; called by muse, mutect2, varscan2
- C10orf71 | c.1519C>T p.R507W | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs554031001, COSV60507319; called by muse, mutect2, varscan2
- C10orf88 | c.498G>T p.M166I | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV64403595, COSV64403852; called by muse, mutect2, varscan2
- C11orf1 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs151235350, COSV99500205; called by muse, mutect2
- C12orf50 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.845); catalogued as rs146317259, COSV53899435; called by muse, mutect2, varscan2
- C12orf50 | c.290-1G>T p.X97_splice | Splice Site (SNP) | VAF 30/60 reads (50%) | catalogued as COSV53893473; called by muse, mutect2, varscan2
- C14orf93 | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1389323910, COSV54440549; called by muse, mutect2
- C15orf39 | c.2608C>T p.R870C | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1443278686; called by muse, mutect2, varscan2
- C16orf87 | c.452G>T p.R151I | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV99587510; called by muse, mutect2, varscan2
- C17orf97 | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.051); catalogued as rs1192355740; called by muse, varscan2
- C1QTNF12 | c.621C>A p.F207L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.99); catalogued as COSV57802259, COSV57803643; called by muse, mutect2, varscan2
- C1QTNF4 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.29); PolyPhen benign (0.28); catalogued as rs767479537; called by muse, mutect2, varscan2
- C1R | c.1798G>A p.D600N (on ENST00000536053 / NM_001354346.2; = p.D586N on NM_001733.7) | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.051); catalogued as rs757372137, COSV101605639; called by muse, mutect2, varscan2
- C1S | c.1945G>A p.A649T | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as rs1555163103, COSV61071827; called by muse, mutect2, varscan2
- C1orf43 | c.341-1G>T p.X114_splice (on ENST00000368521 / NM_001297718.2; = p.X80_splice on NM_015449.4) | Splice Site (SNP) | VAF 25/54 reads (46%) | catalogued as COSV100634299; called by muse, mutect2, varscan2
- C20orf194 | c.1022C>T p.S341L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as rs200531397; called by muse, varscan2
- C2CD2 | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.74); PolyPhen benign (0.125); catalogued as rs747708713; called by muse, mutect2, varscan2
- C2CD3 | c.4103C>T p.S1368F | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV58091600; called by muse, mutect2, varscan2
- C2CD5 | c.284C>A p.P95H | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61725262; called by muse, mutect2, varscan2
- C2orf49 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs199899473; called by muse, mutect2, varscan2
- C2orf78 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs774126811, COSV68518562; called by muse, mutect2, varscan2
- C2orf80 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs987661802, COSV58015332; called by muse, mutect2, varscan2
- C3 | c.2866G>T p.G956* | Nonsense Mutation (SNP) | VAF 22/52 reads (42%) | catalogued as COSV55582141; called by muse, mutect2
- C3 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs373896614; called by muse, mutect2, varscan2
- C3orf14 | c.49G>T p.E17* | Nonsense Mutation (SNP) | VAF 12/25 reads (48%) | catalogued as rs1024244540; called by muse, mutect2, varscan2
- C3orf38 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.073); catalogued as rs367988869; called by muse, mutect2, varscan2
- C3orf70 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs558605400; called by muse, mutect2, varscan2
- C5 | c.526G>T p.E176* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as rs1459526637; called by muse, mutect2, varscan2
- C5orf38 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs772380035, COSV100121673, COSV57412756, COSV57414154; called by muse, varscan2
- C5orf49 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.365); catalogued as rs200685152; called by muse, mutect2, varscan2
- C6orf58 | c.389-1G>A p.X130_splice | Splice Site (SNP) | VAF 34/58 reads (59%) | catalogued as COSV61666298; called by muse, mutect2, varscan2
- C7 | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as rs537357253, COSV57470694, COSV57477507; called by muse, mutect2, varscan2
- C7orf57 | c.323G>A p.S108N | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.285); catalogued as rs1390459363; called by muse, mutect2, varscan2
- C8A | c.415G>T p.D139Y | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.69); catalogued as COSV63483235; called by muse, mutect2, varscan2
- C8A | c.1283C>A p.S428Y | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs1292711300; called by muse, varscan2
- C9orf43 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs758663749; called by muse, mutect2, varscan2
- C9orf43 | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as rs771894456, COSV99928326; called by muse, mutect2, varscan2
- C9orf50 | c.1141C>T p.R381* | Nonsense Mutation (SNP) | VAF 24/47 reads (51%) | catalogued as rs570920263; called by muse, mutect2, varscan2
- CA11 | c.865C>T p.R289W | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755381208, COSV50033088; called by muse, mutect2, varscan2
- CA2 | c.143C>A p.S48Y | Missense Mutation (SNP) | VAF 77/122 reads (63%) | SIFT tolerated (0.39); PolyPhen benign (0.063); catalogued as CD972104, COSV53405619; called by muse, mutect2, varscan2
- CA5A | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs200681449, COSV59238863; called by muse, mutect2, varscan2
- CAAP1 | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1264949189; called by muse, mutect2, varscan2
- CAB39 | c.829G>A p.V277I | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as rs1366529396; called by muse, mutect2, varscan2
- CABP4 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770118394, COSV56885910; called by muse, mutect2, varscan2
- CABS1 | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs773366011, COSV56734988; called by muse, mutect2, varscan2
- CACHD1 | c.2324C>A p.P775H | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51553416; called by muse, mutect2, varscan2
- CACNA1A | c.3937C>T p.R1313C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV64196442; called by muse, mutect2, varscan2
- CACNA1B | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.646); catalogued as rs768660275, COSV53115105; called by muse, varscan2
- CACNA1C | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 52/96 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as COSV100218328; called by muse, mutect2, varscan2
- CACNA1C | c.1102G>A p.V368M | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs768152404; called by muse, mutect2, varscan2
- CACNA1E | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV100702725; called by muse, mutect2, varscan2
- CACNA1E | c.2771G>A p.R924H | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs764081616, COSV100701288, COSV100705611; called by muse, mutect2, varscan2
- CACNA2D1 | c.196G>T p.D66Y | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as COSV62375168; called by muse, mutect2, varscan2
- CACNA2D2 | c.1264C>T p.R422C | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56560122; called by muse, mutect2, varscan2
- CACNA2D4 | c.2717G>A p.R906Q | Missense Mutation (SNP) | VAF 42/68 reads (62%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs189066664; called by muse, varscan2
- CACNB2 | c.1659G>T p.E553D (on ENST00000324631 / NM_201596.3; = p.E498D on NM_000724.4) | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as CM127057; called by muse, mutect2, varscan2
- CACNB2 | c.1757G>A p.R586H (on ENST00000324631 / NM_201596.3; = p.R531H on NM_000724.4) | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747168096, COSV56637002; called by muse, varscan2
- CACNB2 | c.1858G>A p.E620K (on ENST00000324631 / NM_201596.3; = p.E565K on NM_000724.4) | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.218); catalogued as rs761643494, COSV56638507; ClinVar: uncertain significance; called by muse, varscan2
- CACNG3 | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as rs1265586977, COSV50071761; called by muse, mutect2, varscan2
- CACNG5 | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as rs201854089; called by muse, mutect2, varscan2
- CACNG7 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs370720912; called by muse, mutect2, varscan2
- CACYBP | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1194296822; called by muse, mutect2, varscan2
- CAD | c.3325C>T p.R1109C | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as rs1391369177; called by muse, mutect2, varscan2
- CAD | c.4613C>T p.S1538L | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as rs1178918865; called by muse, mutect2, varscan2
- CADM4 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV55928371; called by muse, mutect2, varscan2
- CADPS | c.1741G>A p.D581N | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs1439217349, COSV51898164; called by muse, mutect2, varscan2
- CADPS2 | c.1639G>A p.D547N | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs745324331, COSV57371961; called by muse, mutect2, varscan2
- CALCOCO1 | c.1036C>T p.R346* | Nonsense Mutation (SNP) | VAF 26/49 reads (53%) | catalogued as COSV100017230; called by muse, mutect2, varscan2
- CALCRL | c.178G>T p.A60S | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV66476287; called by muse, mutect2, varscan2
- CALML5 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs199855788, COSV100981195; called by muse, mutect2, varscan2
- CAMK1D | c.448C>A p.L150I | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV66608344; called by muse, mutect2, varscan2
- CAMK2D | c.761C>A p.T254N | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99594578; called by muse, mutect2, varscan2
- CAMK2G | c.219C>T p.I73= | Splice Region (SNP) | VAF 11/49 reads (22%) | catalogued as rs759276317, COSV59486267; called by muse, mutect2, varscan2
- CAMK4 | c.536C>A p.A179E | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100000397; called by muse, mutect2, varscan2
- CAMKMT | c.523C>A p.L175M | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV65930334; called by muse, mutect2, varscan2
- CAMKV | c.225G>T p.K75N | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); catalogued as COSV56554600, COSV56555224; called by muse, mutect2, varscan2
- CAMSAP1 | c.3356G>A p.R1119Q | Missense Mutation (SNP) | VAF 44/74 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs756147112, COSV56721981; called by muse, mutect2, varscan2
- CAMTA1 | c.1851C>A p.F617L | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV57920745; called by muse, mutect2, varscan2
- CAND1 | c.2890G>T p.E964* | Nonsense Mutation (SNP) | VAF 20/44 reads (45%) | catalogued as COSV73389645; called by muse, mutect2, varscan2
- CAND2 | c.1033G>A p.D345N (on ENST00000456430 / NM_001162499.2; = p.D252N on NM_012298.3) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs757397927, COSV55992875; called by muse, varscan2
- CAPN3 | c.676G>T p.E226* | Nonsense Mutation (SNP) | VAF 17/92 reads (18%) | catalogued as CM990306; called by muse, mutect2, varscan2
- CAPN3 | c.1796C>A p.T599N | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs768832864, COSV58822949; called by muse, mutect2, varscan2
- CAPN5 | c.1144G>A p.V382M (on ENST00000456580; = p.V342M on NM_004055.5) | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs371777752; called by muse, mutect2, varscan2
- CAPN6 | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749267304; called by muse, mutect2, varscan2
- CAPN7 | c.1415G>A p.R472Q | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.292); catalogued as rs777257185; called by mutect2, varscan2
- CAPRIN1 | c.1796G>A p.R599H | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as rs777495008; called by muse, mutect2, varscan2
- CARD11 | c.767A>G p.D256G | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV101210580; called by muse, mutect2, varscan2
- CARD11 | c.337C>T p.R113W | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV62716211; called by muse, mutect2, varscan2
- CARD6 | c.2316G>T p.Q772H | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as rs377178602; called by muse, mutect2, varscan2
- CARD8 | c.982G>A p.E328K (on ENST00000651546 / NM_001184900.3; = p.E278K on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.989); catalogued as rs758242862, COSV62872805; called by muse, mutect2, varscan2
- CARF | c.183G>T p.Q61H | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV57547473; called by muse, mutect2, varscan2
- CARF | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.365); catalogued as rs758931336, COSV100247704; called by muse, varscan2
- CARF | c.2002C>A p.L668M | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as COSV57546385; called by muse, mutect2, varscan2
- CARMIL1 | c.2788C>T p.R930W | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61525502; called by muse, mutect2, varscan2
- CARMIL2 | c.3284G>A p.R1095Q | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs1336504683, COSV99537630; called by muse, mutect2, varscan2
- CARNS1 | c.1633G>A p.V545I | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.545); catalogued as rs749983290; called by muse, mutect2, varscan2
- CARS2 | c.1368C>A p.Y456* | Nonsense Mutation (SNP) | VAF 15/25 reads (60%) | catalogued as rs1422936298; called by muse, mutect2, varscan2
- CASD1 | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as COSV51974004; called by muse, mutect2, varscan2
- CASKIN2 | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.837); catalogued as rs756458899; called by muse, mutect2, varscan2
- CASP10 | c.1124G>A p.R375Q (on ENST00000272879 / NM_032974.5; = p.R332Q on NM_001230.5) | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.477); catalogued as rs375798142; called by muse, mutect2, varscan2
- CASP2 | c.1126G>A p.A376T | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs898981516, COSV100130906; called by muse, varscan2
- CASP2 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs188499115; called by muse, varscan2
- CASP5 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.836); catalogued as COSV52830397; called by muse, mutect2, varscan2
- CASP8 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.26); catalogued as rs1339962485, COSV51846409, COSV51847390, COSV51855757; called by muse, mutect2, varscan2
- CASP8AP2 | c.1295G>T p.R432I | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771388693; called by muse, varscan2
- CASQ2 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121434549, CM013693, COSV54770079; called by muse, mutect2, varscan2
- CASR | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1313627454, CM124124, COSV56135610; called by muse, mutect2, varscan2
- CASZ1 | c.1750G>A p.D584N | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs767859349, COSV59740297; called by muse, mutect2, varscan2
- CATSPER1 | c.2027C>T p.T676M | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs376917892; called by muse, mutect2, varscan2
- CATSPER2 | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.93); catalogued as rs774680387, COSV58661497; called by muse, mutect2, varscan2
- CATSPER3 | c.841G>T p.E281* | Nonsense Mutation (SNP) | VAF 27/54 reads (50%) | catalogued as COSV50947512; called by muse, mutect2, varscan2
- CATSPERB | c.2456C>T p.T819M | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs748919841, COSV56424329; called by muse, varscan2
- CATSPERB | c.1981C>T p.P661S | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56423599; called by muse, mutect2, varscan2
- CAV3 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT tolerated (0.14); PolyPhen benign (0.124); catalogued as rs868638613, COSV57479125; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAVIN2 | c.348G>T p.E116D | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as COSV58425143; called by muse, mutect2, varscan2
- CAVIN4 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs200590850; ClinVar: uncertain significance; called by muse, varscan2
- CBFA2T3 | c.893G>T p.R298M | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1216016294; called by muse, mutect2
- CBFA2T3 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.025); catalogued as rs776031429, COSV51923006; called by muse, mutect2, varscan2
- CBL | c.2656G>A p.E886K | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.385); catalogued as rs1435757249; called by muse, mutect2, varscan2
- CBLL2 | c.974G>T p.G325V | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV100081584; called by muse, mutect2, varscan2
- CBLL2 | c.1268G>A p.R423K | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.945); catalogued as COSV60369541; called by muse, mutect2, varscan2
- CBX1 | c.88C>T p.R30* | Nonsense Mutation (SNP) | VAF 60/122 reads (49%) | catalogued as COSV56681749, COSV56682056; called by muse, mutect2, varscan2
- CC2D1B | c.1882C>A p.L628M | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.367); catalogued as COSV52562333; called by muse, mutect2, varscan2
- CCAR1 | c.1066C>T p.R356* | Nonsense Mutation (SNP) | VAF 7/39 reads (18%) | catalogued as COSV56269292; called by muse, mutect2, varscan2
- CCAR2 | c.2633C>T p.A878V | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs769836001; called by muse, mutect2
- CCDC102A | c.808C>T p.R270* | Nonsense Mutation (SNP) | VAF 5/43 reads (12%) | catalogued as rs771934534; called by mutect2, varscan2
14,232 further variants in this file (10,908 protein-altering or splice-affecting, 2,975 silent, 349 other) are not listed here.
